CCDI case PBBTTZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6c78d4d5-c101-4c78-aacd-9728b681bcc5

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (475 days).

Biospecimens (3 samples)
- Sample 0DGQAJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGQAN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGQBE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
